Gene-level copy-number profile of tumor specimen TCGA-GC-A3BM-01A from TCGA case TCGA-GC-A3BM, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Dome of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 70.1 years (25,609 days).
Specimen TCGA-GC-A3BM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.e9b73d3f-bd84-4cab-b719-ffa71cbd7dc2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GC-A3BM-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/34be379a-f0a5-434a-8cff-1f596b0e1772

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 45; copy number 1: 7; copy number 2: 13,680; copy number 3: 10,806; copy number 4: 33,261; copy number 5: 639; copy number 6: 1,215; copy number 7: 142; copy number 10: 8; copy number 11: 9; copy number 12: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GC-A3BM-01A-11D-A22Y-01): tumor purity 0.86, ploidy 3.38, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 45 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:49,828,601–50,504,244, 41 genes (within-gene range 0–3): TRAIP, CAMKV, RN7SL217P, ACTBP13, MST1R, AC105935.2, AC105935.1, MON1A, RBM6, RBM5, RBM5-AS1, SEMA3F-AS1, SEMA3F, AC104450.1, GNAT1, SLC38A3, GNAI2, MIR5787, U73169.1, U73166.1, SEMA3B-AS1, SEMA3B, MIR6872, LSMEM2, IFRD2, HYAL3, NAA80, HYAL1, HYAL2, TUSC2, RASSF1, RASSF1-AS1, ZMYND10-AS1, ZMYND10, NPRL2, CYB561D2, Z84492.2, TMEM115, CACNA2D2, Z84492.1, RNA5SP131.
- chr17:7,686,071–7,833,744, 4 genes (within-gene range 0–2): WRAP53, EFNB3, DNAH2, RPL29P2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 19 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:78,324,758–78,582,156, 8 genes, copy number 10 (within-gene range 6–10): AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3.
- chr11:81,552,226–81,556,425, 2 genes, copy number 12: MTND4LP18, MTND6P25.
- chr11:90,972,316–91,383,289, 9 genes, copy number 11: AP001002.3, AP001002.1, AP001002.2, OSBPL9P2, OSBPL9P3, LINC02748, AP003485.2, AP003485.1, AP002791.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
